TARGET case TARGET-30-PAHYWC — Neuroblastoma (TARGET-NBL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neuroepitheliomatous Neoplasms. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/473366ce-4bbf-5d4d-abd8-8f1e5caa3d50

Demographics
Sex at birth: male; Race: white; Age at index: 1 years; Vital status: Dead; Days to death: 437 days (1.2 years).

Diagnoses (1)
1. Neuroblastoma, NOS: ICD-O-3 morphology code: 9500/3; ICD-10 code: C80.0; Classification of tumor: primary; Age at diagnosis: 1.9 years (704 days); Year of diagnosis: 1993; Days to last follow up: 437 days (1.2 years); Cog neuroblastoma risk group: High Risk; INSS stage: Stage 4.
   Pathology details: Necrosis percent: 15; Percent tumor nuclei: 85.
   Treatment given: Protocol identifier: 9340.
   Treatment given: Protocol identifier: 9047.

Follow-up (2 entries)
- Days to follow up: 324 days; Days to first event: 324 days; First event: Event.
- Days to follow up: 437 days (1.2 years); Year of follow up: 1994.

Molecular and laboratory tests
- MYCN amplification: Amplified.
- Test: Normal; Ploidy: Diploid.

Biospecimens (2 samples)
- Sample TARGET-30-PAHYWC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
- Sample TARGET-30-PAHYWC-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_NBL_ClinicalData_Discovery_20230523.xlsx (sheet Clinical Data):
- First Event: Event
- Overall Survival Time in Days: 437
- Protocol: 9047, 9340
- Ploidy: Diploid (DI=1)
- Ploidy Value: 1
- ICDO Description: ABDOMEN/PERITONEUM OR RETROPERITONEUM
- Percent Tumor v/s Stroma: 95/5
